Somatic mutation profile of tumor specimen TCGA-23-1124-01A (aliquot TCGA-23-1124-01A-01W-0488-09) from TCGA case TCGA-23-1124, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.0 years (23,005 days).
Specimen TCGA-23-1124-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e1482db-586e-48e7-924b-ffee5965e9ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1124-10A (Blood Derived Normal), aliquot TCGA-23-1124-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4384b6f4-0aa0-4859-97a3-7c6b1bf8ece4

The open-access MAF lists 166 somatic variants for this specimen: 131 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 30, Splice Site 6, Frame Shift Del 5, Intron 2, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, In Frame Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS6 | c.2509G>C p.D837H | Missense Mutation (SNP) | VAF 77/112 reads (69%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV66861542; called by muse, mutect2, varscan2
- ADGRV1 | c.7271G>A p.R2424K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.067); catalogued as COSV67988951; called by muse, mutect2, varscan2
- AGBL2 | c.2574G>C p.K858N | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV54093423; called by muse, mutect2, varscan2
- AKAP13 | c.5237G>T p.S1746I (on ENST00000394518 / NM_007200.5; = p.S1750I on NM_006738.6) | Missense Mutation (SNP) | VAF 109/767 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63462827; called by muse, mutect2, varscan2
- AKAP8L | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV101275699; called by muse, mutect2
- AKAP9 | c.3486G>C p.Q1162H | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.061); catalogued as COSV62350586, COSV62352748; called by muse, mutect2
- ARFIP1 | c.880C>G p.Q294E (on ENST00000353617 / NM_001287432.1; = p.Q262E on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61885277; called by muse, mutect2, varscan2
- ATAD2B | c.3605C>G p.S1202C | Missense Mutation (SNP) | VAF 81/355 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); catalogued as COSV53201567; called by muse, mutect2, varscan2
- BDKRB2 | c.1081A>T p.I361F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV60015631; called by muse, mutect2, varscan2
- BHMT | c.1016C>G p.T339S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV57154882; called by muse, mutect2, varscan2
- BMP2K | c.1079C>G p.T360S | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.076); catalogued as COSV58596583; called by muse, mutect2, varscan2
- BSN | c.10671G>T p.E3557D | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as COSV56521652; called by muse, mutect2, varscan2
- C9orf24 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as rs1165709635, COSV52624756; called by muse, mutect2, varscan2
- CA14 | c.257-1G>A p.X86_splice | Splice Site (SNP) | VAF 74/306 reads (24%) | catalogued as rs1348749294, COSV52529795; called by muse, mutect2, varscan2
- CCDC172 | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV60938452, COSV60939222; called by muse, mutect2, varscan2
- CCDC183 | c.576G>C p.K192N | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV62013069; called by muse, mutect2, varscan2
- CCN3 | c.523C>G p.P175A | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52384361; called by muse, mutect2, varscan2
- CD163 | c.723A>T p.Q241H | Missense Mutation (SNP) | VAF 197/1281 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.366); catalogued as COSV63134455; called by muse, mutect2, varscan2
- CDCA7 | c.752A>G p.E251G (on ENST00000347703 / NM_145810.3; = p.E330G on NM_031942.5) | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV60720760; called by muse, mutect2, varscan2
- CDH16 | c.1184C>G p.P395R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.02); catalogued as COSV55337728; called by muse, mutect2, varscan2
- CEACAM21 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51814867; called by muse, mutect2, varscan2
- CEP83 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV100352584; called by muse, mutect2
- CFAP43 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.638); catalogued as COSV53379123; called by muse, mutect2, varscan2
- CPB2 | c.1240A>C p.K414Q | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV51675579; called by muse, mutect2, varscan2
- CPS1 | c.2540G>C p.S847T | Missense Mutation (SNP) | VAF 175/272 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51802509, COSV51815034; called by muse, mutect2, varscan2
- CSF3 | c.41-1G>A p.X14_splice | Splice Site (SNP) | VAF 3/18 reads (17%) | catalogued as COSV56641350; called by muse, mutect2
- CYP11A1 | c.1164C>A p.H388Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537187397, COSV51433001; called by muse, mutect2, varscan2
- CYP21A2 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as CM122727, COSV100925680; called by muse, mutect2, varscan2
- CYP2C9 | c.1332G>C p.E444D | Missense Mutation (SNP) | VAF 156/594 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53250167, COSV99582961; called by muse, mutect2, varscan2
- DDX24 | c.865G>C p.G289R | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV58212928; called by muse, mutect2, varscan2
- DGKB | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs982542800, COSV51796521; called by muse, mutect2, varscan2
- DMXL2 | c.2891T>C p.L964P | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51849728; called by muse, mutect2, varscan2
- DNAH7 | c.3343A>G p.T1115A | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV100413482; called by muse, mutect2
- DSCAM | c.5069A>C p.D1690A | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV68030048; called by muse, mutect2, varscan2
- ENPP1 | c.2716G>C p.E906Q | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV62933708; called by muse, mutect2, varscan2
- FAM155B | c.1244C>A p.P415H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99368086, COSV99368099; called by muse, mutect2
- FAM187B | c.150C>A p.H50Q | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV61201479; called by muse, mutect2, varscan2
- FRZB | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54554793; called by muse, mutect2, varscan2
- GINS1 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 227/256 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52465748, COSV99319985; called by muse, mutect2, varscan2
- GLS2 | c.1650C>A p.D550E | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57665707; called by muse, mutect2, varscan2
- GOLGA2 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.698); catalogued as COSV68597356; called by muse, mutect2, varscan2
- GPR149 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs747484911, COSV67668170; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2387C>G p.T796S | Missense Mutation (SNP) | VAF 55/428 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.389); catalogued as COSV63100530; called by muse, mutect2, varscan2
- HHEX | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV51106620; called by muse, mutect2, varscan2
- HTR5A | c.889T>G p.C297G | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55284646; called by muse, mutect2, varscan2
- IGHD | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV66655265; called by muse, mutect2, varscan2
- IKZF4 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.063); catalogued as COSV56267184, COSV56269605; called by muse, mutect2, varscan2
- IZUMO1R | c.363T>A p.N121K (on ENST00000440961; = p.N128K on NM_001199206.3) | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.373); catalogued as rs1201248218, COSV100126899, COSV60623053; called by muse, mutect2, varscan2
- KDELR3 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs752571011, COSV53248601; called by muse, mutect2, varscan2
- KDELR3 | c.581T>A p.F194Y | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs756093412, COSV53248616; called by muse, mutect2, varscan2
- KDM7A | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV50092815; called by muse, mutect2, varscan2
- KLF12 | c.1003A>G p.K335E | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV66575410; called by muse, mutect2, varscan2
- LECT2 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV50847367; called by muse, mutect2, varscan2
- LPAR4 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70912945, COSV70913207, COSV70913547; called by muse, mutect2, varscan2
- LRRC1 | c.344A>T p.N115I | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV63824442; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | catalogued as rs765962881; called by mutect2, varscan2
- MBTPS1 | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV58571490; called by muse, mutect2, varscan2
- MFSD11 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV60625537; called by muse, mutect2, varscan2
- MGAT1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 10/11 reads (91%) | PolyPhen probably damaging (1); catalogued as rs1184766082, COSV57133158; called by muse, mutect2, varscan2
- MKRN1 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV55437535; called by muse, mutect2, varscan2
- MLXIP | c.2495G>T p.W832L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59836437; called by muse, mutect2, varscan2
- MMP10 | c.921del p.F308Lfs*20 | Frame Shift Del (DEL) | VAF 44/302 reads (15%) | catalogued as COSV104380172; called by mutect2, pindel, varscan2
- MOSPD1 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 91/125 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV66189412; called by muse, mutect2, varscan2
- MPI | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60397129; called by muse, mutect2, varscan2
- MTFR1L | c.638G>T p.C213F | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.61); catalogued as COSV100961766; called by muse, mutect2
- MYCBP2 | c.13407G>C p.M4469I (on ENST00000357337; = p.M4507I on NM_015057.5) | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV62026818; called by muse, mutect2, varscan2
- MYH11 | c.2357T>C p.I786T | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55558736; called by muse, mutect2, varscan2
- NAV3 | c.5875C>T p.R1959C (on ENST00000397909 / NM_001024383.2; = p.R1937C on NM_014903.6) | Missense Mutation (SNP) | VAF 90/149 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs573838509, COSV57091466; called by muse, mutect2, varscan2
- NCAPD3 | c.4174+1G>T p.X1392_splice | Splice Site (SNP) | VAF 82/287 reads (29%) | catalogued as rs1319843949, COSV73187882; called by muse, mutect2, varscan2
- NSMCE3 | c.712A>T p.I238L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV99720438; called by muse, mutect2, varscan2
- NWD1 | c.722C>G p.T241S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60345236; called by muse, mutect2, varscan2
- OTX2 | c.302A>C p.Q101P (on ENST00000408990 / NM_172337.3; = p.Q109P on NM_021728.4) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as COSV59766712; called by muse, mutect2, varscan2
- PBX4 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 49/395 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV52062354; called by mutect2, varscan2
- PLA2G4F | c.2024G>C p.C675S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51827755; called by muse, mutect2, varscan2
- PLCZ1 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 72/391 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56855235; called by muse, mutect2, varscan2
- POGZ | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 128/262 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs748616193, COSV55038145; called by muse, mutect2, varscan2
- POU4F1 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV65884662; called by mutect2, varscan2
- PPP3CC | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51501816; called by muse, mutect2, varscan2
- PRAMEF12 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63215787; called by muse, mutect2, varscan2
- PRKCB | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV57787184; called by muse, mutect2, varscan2
- PROKR1 | c.995T>G p.M332R | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58138182; called by muse, mutect2, varscan2
- PSG8 | c.1277T>C p.I426T | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV100125925; called by muse, mutect2
- PTPRF | c.2688C>G p.N896K | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1186558185, COSV63446352; called by muse, mutect2
- RBMX | c.1159G>C p.G387R | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.637); catalogued as COSV100284476, COSV57810129; called by muse, mutect2, varscan2
- RPGRIP1L | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV50904667, COSV50909492; called by muse, mutect2, varscan2
- RXRB | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63399829; called by muse, mutect2, varscan2
- SDC1 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV54340427; called by muse, mutect2, varscan2
- SEC14L1 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs774609620, COSV66723273; called by muse, mutect2, varscan2
- SEC23B | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99357316; called by muse, mutect2
- SF3A1 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53169831; called by muse, mutect2, varscan2
- SLC38A11 | c.362T>A p.L121H (on ENST00000409149 / NM_001351539.1; = p.L99H on NM_173512.2) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58054658; called by muse, mutect2, varscan2
- SLC4A5 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs374602113; called by muse, mutect2, varscan2
- SLC4A5 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as COSV61029737; called by muse, mutect2, varscan2
- SLC52A3 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV54078049; called by muse, mutect2, varscan2
- SLC6A3 | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV54365744, COSV54365944; called by muse, mutect2, varscan2
- SPP1 | c.685C>A p.Q229K (on ENST00000395080 / NM_001040058.2; = p.Q215K on NM_000582.2) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV52952068; called by muse, mutect2, varscan2
- STXBP3 | c.439-2A>T p.X147_splice | Splice Site (SNP) | VAF 29/186 reads (16%) | catalogued as COSV64182100; called by muse, mutect2, varscan2
- STYXL2 | c.2891G>A p.R964K | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as rs769537426, COSV54806907; called by muse, mutect2, varscan2
- SWAP70 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV59665035; called by muse, mutect2, varscan2
- TAS2R8 | c.437T>A p.L146H | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53689390; called by muse, mutect2, varscan2
- TIMMDC1 | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51787176; called by muse, mutect2, varscan2
- TLE6 | c.1361C>A p.P454H (on ENST00000246112 / NM_001143986.2; = p.P331H on NM_024760.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55736416, COSV55737080; called by muse, mutect2, varscan2
- TM7SF2 | c.598G>C p.G200R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54208126; called by muse, mutect2, varscan2
- TNS3 | c.850A>C p.K284Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV60793848; called by muse, mutect2, varscan2
- TRAJ3 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as rs1390778817; called by muse, mutect2, varscan2
- TRPV3 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 98/143 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.2); catalogued as rs758875463, COSV56792615; called by muse, mutect2, varscan2
- TTC3 | c.3361C>G p.H1121D | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV61292554; called by muse, mutect2, varscan2
- UACA | c.3881A>G p.D1294G | Missense Mutation (SNP) | VAF 106/461 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1005420623, COSV59857224; called by muse, mutect2, varscan2
- UBA7 | c.1581C>A p.N527K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV61092638; called by muse, mutect2, varscan2
- USP2 | c.604T>A p.Y202N | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); catalogued as COSV99489232; called by muse, mutect2
- USP2 | c.603C>G p.N201K | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV52728260, COSV99489234; called by muse, mutect2
- USP33 | c.2273C>G p.P758R | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62470142; called by muse, mutect2, varscan2
- USP7 | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61215708; called by muse, varscan2
- WDR47 | c.1130+1G>A p.X377_splice | Splice Site (SNP) | VAF 44/223 reads (20%) | catalogued as COSV100728212; called by muse, mutect2, varscan2
- WIF1 | c.1091A>G p.K364R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV54133184; called by muse, mutect2, varscan2
- YES1 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 30/149 reads (20%) | catalogued as rs1354676545, COSV58848775; called by muse, mutect2, varscan2
- ZNF14 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1055598017, COSV59850232; called by muse, mutect2, varscan2
- ZNF16 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 78/556 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52764451; called by muse, mutect2, varscan2
- ZNF326 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 209/401 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV61035735; called by muse, mutect2, varscan2
- ADCK2 | c.1798del p.G601Afs*63 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, pindel
- CYFIP1 | c.2472G>A p.M824I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IGLV1-44 | c.245T>A p.F82Y | Missense Mutation (SNP) | VAF 112/478 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.324); called by muse, varscan2
- INPPL1 | c.1300+2_1300+27del p.X434_splice | Splice Site (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- KRT72 | c.396_407del p.N133_F136del | In Frame Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, varscan2
- MPHOSPH8 | c.2534C>T p.S845F | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- MYLK2 | c.644_665del p.A215Gfs*53 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel
- PSAPL1 | c.458T>G p.L153R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); called by muse, mutect2
- TRAV21 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.325); called by muse, mutect2
- XIRP2 | c.1894_1910del p.K632* (on ENST00000628543; = p.K807* on NM_152381.6) | Frame Shift Del (DEL) | VAF 108/218 reads (50%) | called by mutect2, pindel, varscan2
- ZCWPW1 | c.1216_1244del p.M406Hfs*6 | Frame Shift Del (DEL) | VAF 60/572 reads (10%) | called by mutect2, pindel
- ACP6 | c.330C>T p.Y110= | Silent (SNP) | VAF 34/172 reads (20%) | catalogued as COSV65077333; called by muse, mutect2, varscan2
- AK9 | c.3498A>G p.E1166= | Silent (SNP) | VAF 57/113 reads (50%) | catalogued as COSV58144892; called by muse, mutect2, varscan2
- ATRX | c.5220A>C p.S1740= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV100969847; called by muse, mutect2, varscan2
- FMNL2 | c.480C>T p.S160= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV56498253; called by muse, mutect2, varscan2
- GRIP1 | c.909C>A p.S303= | Silent (SNP) | VAF 64/94 reads (68%) | catalogued as COSV54030059; called by muse, mutect2, varscan2
- MPP7 | c.1143G>A p.L381= | Silent (SNP) | VAF 16/361 reads (4%) | catalogued as COSV100516774; called by muse, mutect2
- NIM1K | c.1011C>T p.F337= | Silent (SNP) | VAF 71/300 reads (24%) | catalogued as COSV58143066; called by muse, mutect2, varscan2
- NSMCE3 | c.711G>A p.R237= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99720439; called by muse, mutect2, varscan2
- NUP210L | c.1071A>G p.G357= | Silent (SNP) | VAF 10/198 reads (5%) | catalogued as COSV55144266, COSV99667017; called by muse, mutect2
- OR11H4 | c.255C>T p.S85= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as COSV100197587, COSV59560507; called by muse, mutect2, varscan2
- OR51B2 | c.522T>G p.R174= | Silent (SNP) | VAF 50/196 reads (26%) | catalogued as COSV60915823, COSV60917071; called by muse, mutect2, varscan2
- OR52H1 | c.198C>G p.S66= (on ENST00000322653; = p.S72= on NM_001005289.1) | Silent (SNP) | VAF 56/240 reads (23%) | catalogued as COSV59505658, COSV59506410; called by muse, mutect2
- PALLD | c.2520C>T p.H840= (on ENST00000505667 / NM_001166108.2; = p.H823= on NM_016081.4) | Silent (SNP) | VAF 73/179 reads (41%) | catalogued as COSV54985111; called by muse, mutect2, varscan2
- PCDHGA1 | c.1911G>A p.A637= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs763255155, COSV65296062; called by muse, mutect2, varscan2
- PGF | c.282T>C p.C94= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99462155; called by muse, mutect2
- PLEKHO2 | c.1206C>A p.P402= | Silent (SNP) | VAF 46/62 reads (74%) | catalogued as COSV60262371, COSV60263337; called by muse, mutect2, varscan2
- POLM | c.192C>T p.S64= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs745946699, COSV54243124; called by muse, mutect2, varscan2
- RBPMS | c.72G>C p.R24= | Silent (SNP) | VAF 134/233 reads (58%) | catalogued as COSV55124616; called by muse, mutect2, varscan2
- SLC5A11 | c.816G>T p.P272= | Silent (SNP) | VAF 250/782 reads (32%) | catalogued as COSV61742379; called by muse, mutect2, varscan2
- SMARCA4 | c.381T>C p.S127= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100758024; called by muse, mutect2, varscan2
- SMG8 | c.1596T>C p.L532= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV56286040; called by muse, mutect2, varscan2
- SYN2 | c.1254G>T p.L418= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as COSV70285811; called by muse, mutect2, varscan2
- SYNM | c.3918A>G p.T1306= | Silent (SNP) | VAF 61/272 reads (22%) | catalogued as rs782591572, COSV50442568; called by muse, mutect2, varscan2
- TNRC6B | c.5461C>T p.L1821= (on ENST00000454349 / NM_001162501.2; = p.L1711= on NM_015088.3) | Silent (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- TRIM55 | c.114G>A p.V38= | Silent (SNP) | VAF 50/385 reads (13%) | catalogued as COSV52547718; called by muse, mutect2, varscan2
- USP34 | c.4299C>T p.S1433= | Silent (SNP) | VAF 59/410 reads (14%) | catalogued as rs775616779, COSV68403025; called by muse, mutect2, varscan2
- WWC1 | c.3186G>A p.Q1062= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV54653734; called by muse, mutect2, varscan2
- XCR1 | c.720C>T p.P240= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV58569903, COSV58571204; called by muse, mutect2, varscan2
- XKR9 | c.960T>C p.P320= | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as COSV68773143; called by muse, mutect2, varscan2
- ZNF263 | c.186C>T p.L62= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV54597266; called by muse, mutect2, varscan2
- LRRC23 | c.*164C>T | 3'UTR (SNP) | VAF 28/204 reads (14%) | catalogued as rs1174791083, COSV50391042; called by muse, mutect2
- MASP1 | c.1303+5149G>A | Intron (SNP) | VAF 19/86 reads (22%) | catalogued as COSV56225117; called by muse, mutect2, varscan2
- RAP1GAP | c.-148-1748G>A | Intron (SNP) | VAF 7/37 reads (19%) | catalogued as COSV51574332; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928644 T>G | 3'Flank (SNP) | VAF 16/24 reads (67%) | catalogued as COSV60484028, COSV60486986; called by muse, mutect2, varscan2
- SPATA8 | n.834T>C | RNA (SNP) | VAF 22/286 reads (8%) | catalogued as COSV60705051; called by muse, mutect2
